Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6137, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6137-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

SPECIMEN

Right hemicolectomy

CLINICAL NOTES

PRE-OP DIAGNOSIS: Hepatic flexure cancer

POST-OP DIAGNOSIS: Same

GROSS DESCRIPTION

Received fresh in a container labeled "right hemicolectomy" is a segment of bowel consisting of 6 cm of terminal ileum with contiguous 23 cm of proximal colon. The serosal surface is glistening and tan-pink, and there is a moderate amount of attached adipose tissue. There is an unremarkable appendix present, measuring 6.5 cm long x 0.7 cm in diameter. On cut surface, it is without focal lesion, without gross evidence of inflammation. The bowel measures 3.6 cm and 8 cm in circumference at the proximal and distal resection margins respectively. The bowel is opened, and there is a circumscribed 5.3 x 5 cm rubbery white-pink mass located 11 cm proximal to the distal margin. A portion of tumor and of normal tissue are submitted for tissue procurement per the clinical requested. On sectioning, the tumor has a maximum thickness of 1.6 cm, and grossly extends through the muscularis propria and into surrounding adipose tissue. It is 1 cm from the outer surface of the specimen. The remainder of the bowel wall averages 0.5 cm thick and has a tan-pink glistening mucosa with a normal pattern and folds. The adipose tissue is dissected, and soft tan lymph nodes are identified up to 1.8 cm in greatest dimension. RS-17, following fixation.

BLOCK SUMMARY: 1 - proximal and distal resection margins; 2-6 - tumor, including relation to uninvolved tissue; 7 - ileocecal valve; 8 - random colon; 9 - appendix; 10-12 - multiple lymph nodes per block; 13-15 - one sectioned lymph node per block; 16,17 - sectioned largest lymph node.

MICROSCOPIC DESCRIPTION

The following template summaries the findings in this case:

Histologic type: Adenocarcinoma of the colon
Histologic grade: Moderately differentiated
Primary tumor (pT): Adenocarcinoma invades through the full thickness of the bowel wall and into surrounding adipose tissue (pT3).
Proximal margin: Negative
Distal margin: Negative
Circumferential (radial) margin: Negative
Distance of tumor from closest margin: See gross description
Vascular invasion: Not identified
Regional lymph nodes (pN): pN1c. Twenty-one negative lymph nodes are identified and they are negative for malignancy. However in block #12, on deeper levels, there is a tumor nodule identified in fat without histologic evidence of residual lymph node tissue, and

[page 2 of 2]
[REDACTED]

given the presence of this tumor deposit, this is pN1c.

Non-lymph node pericolic tumor: See above

Distant metastasis (pM): pMX

Other findings: Appendix without specific diagnostic abnormalities.

[REDACTED]

[REDACTED]

DIAGNOSIS

Terminal ileum, appendix, and right colon, excision

- Moderately differentiated adenocarcinoma of the colon, invading through the full thickness of the muscularis propria and into

surrounding adipose tissue (see microscopic description).

- Margins negative for malignancy.

- Tumor deposit identified in pericolic fat, and twenty-one lymph nodes negative for malignancy (pN1c).

ific malities.

[REDACTED]

[REDACTED]

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file be6963e2-a9db-4d3e-a34b-c4cb9a93c433 (TCGA-A6-6137.700D53AD-BF88-4B4E-952A-6714E9A74A87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).